Somatic mutation profile of tumor specimen C3N-03020-02 (aliquot CPT0189080011) from CPTAC case C3N-03020, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 65.1 years (23,772 days).
Specimen C3N-03020-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3bd763f9-2a80-4778-83bd-432df57094d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03020-31 (Blood Derived Normal), aliquot CPT0189100002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7832abd0-60a1-4bef-b309-d7a978df25b6

The open-access MAF lists 58 somatic variants for this specimen: 40 protein-altering or splice-affecting, 9 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 9, Intron 7, Frame Shift Del 6, Nonsense Mutation 3, In Frame Del 2, 3'UTR 2, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.452T>C p.I151T | Missense Mutation (SNP) | VAF 118/289 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs869025655, CM1410322, CM994244, COSV56545117, COSV56548828, COSV56550478, COSV56564804; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CNGA2 | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 133/228 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100323380; called by muse, mutect2, varscan2
- COL14A1 | c.3090G>T p.K1030N | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV52869297; called by muse, mutect2, varscan2
- COPG1 | c.1679G>A p.R560K | Missense Mutation (SNP) | VAF 48/204 reads (24%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV100135229; called by muse, mutect2, varscan2
- EHMT1 | c.3673G>A p.A1225T | Missense Mutation (SNP) | VAF 21/314 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1205210407; called by muse, mutect2
- GPR151 | c.972_974del p.M324del | In Frame Del (DEL) | VAF 44/242 reads (18%) | catalogued as rs996034894; called by pindel, varscan2
- GPRASP1 | c.172del p.V58Lfs*60 | Frame Shift Del (DEL) | VAF 77/151 reads (51%) | catalogued as COSV100851093; called by mutect2, pindel, varscan2
- PBRM1 | c.268C>T p.Q90* | Nonsense Mutation (SNP) | VAF 50/119 reads (42%) | catalogued as COSV56300555; called by muse, mutect2, varscan2
- POU4F3 | c.1004C>G p.S335W | Missense Mutation (SNP) | VAF 144/482 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57944205; called by muse, mutect2, varscan2
- TTC7B | c.2137G>A p.A713T | Missense Mutation (SNP) | VAF 130/480 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs556422393; called by muse, mutect2, varscan2
- ACTR1A | c.283T>G p.S95A | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- AEBP1 | c.1283A>G p.Y428C | Missense Mutation (SNP) | VAF 115/360 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ALKAL1 | c.104C>G p.A35G | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- ARHGAP39 | c.533T>G p.F178C | Missense Mutation (SNP) | VAF 96/358 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- CAPN9 | c.1728C>A p.S576R | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CBY3 | c.344A>C p.E115A | Missense Mutation (SNP) | VAF 48/206 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); called by muse, varscan2
- CBY3 | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 50/208 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, varscan2
- CECR2 | c.3946T>G p.F1316V (on ENST00000342247 / NM_001290047.2; = p.F1132V on NM_001290046.1) | Missense Mutation (SNP) | VAF 96/368 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CFAP251 | c.1943del p.K648Rfs*8 | Frame Shift Del (DEL) | VAF 79/240 reads (33%) | called by mutect2, pindel, varscan2
- CR2 | c.86T>C p.I29T | Missense Mutation (SNP) | VAF 81/330 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- CTSC | c.1276A>G p.K426E | Missense Mutation (SNP) | VAF 169/533 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- DDX4 | c.1765G>A p.G589R | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DSEL | c.2163_2167dup p.H723Lfs*8 | Frame Shift Ins (INS) | VAF 36/133 reads (27%) | called by mutect2, varscan2
- GOLIM4 | c.2019_2024del p.Y673_E675delins* | Nonsense Mutation (DEL) | VAF 27/223 reads (12%) | called by pindel, varscan2
- GOLIM4 | c.2012A>C p.E671A | Missense Mutation (SNP) | VAF 35/251 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.848); called by muse, varscan2
- GRIA1 | c.563T>A p.L188H | Missense Mutation (SNP) | VAF 56/211 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- INTS10 | c.2029del p.L677Wfs*14 | Frame Shift Del (DEL) | VAF 81/302 reads (27%) | called by mutect2, pindel, varscan2
- JUP | c.937C>T p.Q313* | Nonsense Mutation (SNP) | VAF 10/106 reads (9%) | called by muse, mutect2
- KNL1 | c.1854T>G p.N618K (on ENST00000346991 / NM_170589.5; = p.N592K on NM_144508.5) | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- LIN37 | c.444+4G>A | Splice Region (SNP) | VAF 119/480 reads (25%) | called by muse, mutect2, varscan2
- PTPN2 | c.789_795del p.D263Efs*8 | Frame Shift Del (DEL) | VAF 18/123 reads (15%) | called by mutect2, pindel, varscan2
- RIMS2 | c.4121C>T p.A1374V (on ENST00000666250 / NM_001348490.2; = p.A945V on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 101/349 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- SETD2 | c.1290del p.D431Ifs*53 | Frame Shift Del (DEL) | VAF 53/146 reads (36%) | called by mutect2, pindel, varscan2
- SLC16A4 | c.961C>T p.H321Y | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SMARCA5 | c.3047A>C p.E1016A | Missense Mutation (SNP) | VAF 58/184 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- SWT1 | c.431T>G p.L144R | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- THAP11 | c.593_598del p.A198_A199del | In Frame Del (DEL) | VAF 62/211 reads (29%) | called by mutect2, pindel, varscan2
- TMEM95 | c.105_114del p.C35Wfs*19 | Frame Shift Del (DEL) | VAF 62/278 reads (22%) | called by mutect2, pindel, varscan2
- TSPYL4 | c.331A>G p.S111G | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- VCPIP1 | c.2066C>T p.P689L | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AFDN | c.2448T>C p.G816= | Silent (SNP) | VAF 68/231 reads (29%) | called by muse, mutect2, varscan2
- BOD1 | c.504C>T p.P168= | Silent (SNP) | VAF 58/329 reads (18%) | called by muse, mutect2, varscan2
- CBY3 | c.345G>A p.E115= | Silent (SNP) | VAF 49/208 reads (24%) | catalogued as COSV65403469; called by muse, varscan2
- CITED2 | c.543C>T p.S181= | Silent (SNP) | VAF 88/258 reads (34%) | catalogued as rs1246978286; called by muse, mutect2, varscan2
- DNAH9 | c.9213C>T p.N3071= | Silent (SNP) | VAF 48/131 reads (37%) | catalogued as rs746628626; called by muse, mutect2, varscan2
- FREM1 | c.4206C>A p.L1402= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as rs777423648; called by muse, varscan2
- MEP1A | c.465C>T p.H155= | Silent (SNP) | VAF 69/209 reads (33%) | catalogued as rs371616881; called by muse, mutect2, varscan2
- MUC17 | c.6921C>T p.N2307= | Silent (SNP) | VAF 43/120 reads (36%) | catalogued as rs766760571, COSV60294973; called by muse, mutect2, varscan2
- SH3PXD2B | c.2406A>C p.P802= | Silent (SNP) | VAF 118/380 reads (31%) | called by muse, mutect2, varscan2
- AP2A1 | c.2115-62T>A | Intron (SNP) | VAF 101/348 reads (29%) | called by muse, mutect2, varscan2
- CFH | c.619+32G>A | Intron (SNP) | VAF 36/129 reads (28%) | called by muse, mutect2, varscan2
- DIXDC1 | c.656+2697A>T | Intron (SNP) | VAF 74/210 reads (35%) | called by muse, mutect2, varscan2
- KLK12 | c.457+16C>T | Intron (SNP) | VAF 38/104 reads (37%) | called by muse, mutect2
- ORAI3 | c.*255A>G | 3'UTR (SNP) | VAF 104/346 reads (30%) | called by muse, mutect2, varscan2
- RGL4 | c.*9C>G | 3'UTR (SNP) | VAF 114/347 reads (33%) | called by muse, mutect2, varscan2
- SH3TC1 | c.481+609C>G | Intron (SNP) | VAF 51/225 reads (23%) | called by muse, mutect2, varscan2
- VPS13D | c.12031-5229G>A | Intron (SNP) | VAF 58/199 reads (29%) | catalogued as rs927710234; called by muse, mutect2, varscan2
- ZFAND1 | c.480+5089A>G | Intron (SNP) | VAF 14/46 reads (30%) | catalogued as rs761086409; called by muse, mutect2, varscan2
